Somatic mutation profile of tumor specimen 0DQVIE from CCDI case PBCFPY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.8 years (2,486 days).
Specimen 0DQVIE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c49f56d-37e7-4110-9c3d-e406c874d8f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQVIZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad3d9913-48ad-439d-ae28-962bed72f438

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, Intron 4, 5'UTR 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 969/1996 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 430/1225 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAP3 | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 450/1267 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs745323169, COSV57644079; called by mutect2, varscan2
- ARHGAP45 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 206/1507 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.735); catalogued as rs979781600; called by muse, mutect2, varscan2
- CBFA2T2 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 908/3034 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1178178637; called by muse, varscan2
- GIPC3 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 110/1288 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs772741956, COSV59259909; called by muse, mutect2
- KCNG1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 122/871 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65369768; called by muse, mutect2, varscan2
- RAD21 | c.9C>G p.Y3* | Nonsense Mutation (SNP) | VAF 250/1827 reads (14%) | catalogued as COSV52056015, COSV52057457; called by muse, mutect2, varscan2
- RNF151 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 203/1329 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs758388088; called by muse, mutect2, varscan2
- RP1L1 | c.6935A>C p.K2312T | Missense Mutation (SNP) | VAF 166/2406 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV66752408; called by muse, mutect2
- RSPH10B | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 309/1781 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs374427152; called by muse, mutect2, varscan2
- ATN1 | c.2768T>A p.L923Q | Missense Mutation (SNP) | VAF 131/1898 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CTNNA2 | c.911A>G p.E304G | Missense Mutation (SNP) | VAF 1036/2232 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERICH3 | c.2233T>A p.F745I | Missense Mutation (SNP) | VAF 644/1488 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by mutect2, varscan2
- LIPA | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 179/2282 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- LTBP3 | c.3695C>T p.P1232L (on ENST00000301873 / NM_001130144.3; = p.P1185L on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/1514 reads (3%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRPS11 | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 68/1320 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2
- MTRES1 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 616/667 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- N4BP3 | c.948G>T p.E316D | Missense Mutation (SNP) | VAF 159/1209 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PICALM | c.572G>C p.G191A | Missense Mutation (SNP) | VAF 838/1759 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- TANC2 | c.2520G>A p.W840* | Nonsense Mutation (SNP) | VAF 176/2279 reads (8%) | called by muse, mutect2
- HS3ST1 | c.651C>T p.G217= | Silent (SNP) | VAF 666/1934 reads (34%) | catalogued as rs779311145; called by muse, mutect2, varscan2
- MAGI3 | c.2700A>G p.G900= | Silent (SNP) | VAF 218/2548 reads (9%) | called by muse, mutect2
- SLC6A19 | c.601C>T p.L201= | Silent (SNP) | VAF 442/1450 reads (30%) | called by muse, mutect2, varscan2
- ZNF317 | c.99C>T p.P33= | Silent (SNP) | VAF 910/1904 reads (48%) | called by muse, mutect2, varscan2
- FAM180B | c.-57C>T | 5'UTR (SNP) | VAF 73/471 reads (15%) | catalogued as rs556745074; called by muse, mutect2, varscan2
- GEMIN2 | c.634-48_634-46del | Intron (DEL) | VAF 200/497 reads (40%) | called by mutect2, pindel, varscan2
- GSPT1 | c.362+12T>A | Intron (SNP) | VAF 75/1038 reads (7%) | called by muse, mutect2
- LCN6 | c.301+65G>A | Intron (SNP) | VAF 83/243 reads (34%) | catalogued as rs1035180820; called by muse, mutect2, varscan2
- LEMD2 | c.778-79G>A | Intron (SNP) | VAF 48/201 reads (24%) | called by muse, mutect2, varscan2
- SLC22A14 | c.-15C>T | 5'UTR (SNP) | VAF 557/1606 reads (35%) | called by muse, mutect2, varscan2
